Surgical pathology report (de-identified scan), TCGA case TCGA-DK-AA74, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DK-AA74-01A (Primary Tumor).

[page 1 of 3]
SURGICAL PATHOLOGY REPORT

Patient Name:

Med. Rec. #:

DOB: (Age:

Gender: M

Ref. Physician:

Patient Address:

Location:

Service: Urology

Accession #:

Date of Procedure:

Date of Receipt:

Date of Report:

Account #:

Billing Type:

Additional Copy to:

Ref. Source:

Clinical Diagnosis & History:

HGT1 on biopsy T3 on imaging and exam

*ICD O-3
Carcinoma, urothelial NOS 8120/3
Site ^{site} Bladder dome C67.1
^{site} Bladder NOS C67.9
JWS 4/30/14*

Specimens Submitted:

1: Bladder, prostate, seminal vesicles, urachus and urethra

DIAGNOSIS:

1. Bladder, prostate, seminal vesicles, urachus and urethra:

Tumor Type:

Invasive urothelial carcinoma, NOS, with focal squamous differentiation

Histologic Grade:

High grade

Pattern of growth of the Non-Invasive component:

Flat (in situ carcinoma)

Pattern of growth of the Invasive component:

Infiltrating

Tumor Multicentricity:

Not identified

Bladder Local Invasion:

Perivesical soft tissues

Extravesical Tumor Extension:

Not identified

Vascular Invasion:

Not identified

Perineural Invasion:

Identified

Surgical Margins:

Free of tumor

Non-Neoplastic Mucosa:

Exhibiting chronic cystitis

Prostate:

Other ; benign with granulomatous inflammation

Seminal Vesicles:

Not involved

Perivesical Lymph Nodes:

Not identified

The Pathologic Stage is (AJCC 2002):

pT3 (Invasion of perivesicle soft tissue)

PR0 (No involvement of prostate)

Comment: The tumor in areas is associated with dense fibrotic/sclerotic stromal reaction including the area adjacent to the left pelvic sidewall margin (inked margin marked by stitch is free of tumor)

[page 2 of 3]
SURGICAL PATHOLOGY REPORT

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Gross Description:

1) The specimen is received fresh labeled, "Bladder, prostate, seminal vesicles, urachus and urethra, stitch marks left pelvic sidewall margin". It consists of a bladder with attached prostate and seminal vesicles measuring 15 cm from superior to inferior, 14.5 cm laterally and 4 cm from anterior to posterior. A stitch marks the left pelvic sidewall margin which is inked orange. The anterior aspect of the bladder is inked blue and the posterior black. The prostatic urethral margin is shaved and submitted. The bladder is opened anteriorly to reveal a tan-pink endophytic granular tumor measuring 6 x 5.7 cm which is grossly situated within the dome and left posterior wall and grossly involve the underlying adipose tissue. Within the bladder is a 4 x 3.5 x 2.2 cm free floating blood clot. The lesion lies 1.5 cm from the left ureteral orifice and 2.5 from the right. Both ureters are probe patent, measuring up to 0.2 cm in maximum diameter. The lesion is sectioned to reveal a maximum depth of invasion is 3.5 cm and grossly approaches the inked fat and pelvic sidewall. The remaining bladder mucosa is tan-pink and focally edematous. Discrete perivesical lymph nodes are not grossly identified. The prostate is serially sectioned to reveal tan nodular cut surfaces. The specimen is representatively submitted including two sections from each prostatic quadrant and transition zone. TPS is submitted. Summary of sections: UM - urethral margin, RUM - right ureter margin, LUM - left ureter margin, RUO - right ureter orifice, LUO - left ureter orifice, FFT-full face of tumor to include dome and left posterior wall, LP - left posterior wall to include tumor LA - left anterior wall, RP - right posterior wall, RA - right anterior wall, TRI - trigone, DOM - dome to include tumor TP-tumor to perivesicular fat, PSW-pelvic sidewall (left, at stitch mark), RSV - right seminal vesicle, LSV - left seminal vesicle RAP - right apex prostate, LAP - left apex prostate, RAM - right anterior mid prostate, RPM - right posterior mid prostate LAM - left anterior mid prostate, LPM - left posterior mid prostate, RAB - right anterior base prostate RPB - right posterior base prostate, LAB - left anterior base prostate, LPB - left posterior base prostate; ADD- additional sections

Summary of Sections:

Part 1: Bladder, prostate, seminal vesicles, urachus and urethra

Blocks	Block Designation	PCs
4	ADD	4
1	DOM	1
5	FFT	5
1	LA	1
1	LAB	1
1	LAM	1
1	LAP	1
1	LP	1
1	LPB	1
1	LPM	1
1	LSV	1
1	LUM	1
1	LUO	1
2	PSW	2
1	RA	1
1	RAB	1
1	RAM	1
1	RAP	1
1	RP	1
1	RPB	1
1	RPM	1
1	RSV	1
1	RUM	1
1	RUO	1
1	TP	1
1	TRI	1

[page 3 of 3]
SURGICAL PATHOLOGY REPORT

1 UM 1

BEG > 90 days
to procurement.

Source: NCI Genomic Data Commons file 1e841fa6-e59a-490e-899e-fc46ed68507a (TCGA-DK-AA74.4734B88D-F4C1-433E-A13F-BE4994766B90.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).